Gene-level copy-number profile of tumor specimen TCGA-ZU-A8S4-01A from TCGA case TCGA-ZU-A8S4, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 52.7 years (19,264 days).
Specimen TCGA-ZU-A8S4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.20eaff28-af32-4ac3-93b6-001d50ea23de.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZU-A8S4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e4b3b43-624e-42a7-9c30-fc6662c17053

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 12,997; copy number 2: 45,798; copy number 3: 897.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZU-A8S4-01A-11D-A416-01): tumor purity 0.28, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 116 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–24,592,104, 33 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.
- chr14:21,978,459–22,518,871, 83 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,583. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
